TCGA case TCGA-IC-A6RF — Esophageal Carcinoma (TCGA-ESCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Esophagus; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9dfddc49-1e66-4e26-9d71-40d748cca0a6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 69 years; Vital status: Alive.

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C15.5; Tissue or organ of origin: Lower third of esophagus; Site of resection or biopsy: Esophagus, NOS; Classification of tumor: primary; Age at diagnosis: 69.6 years (25,417 days); Year of diagnosis: 2013; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC clinical T: T1; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage IIB; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Tumor grade: GX; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 477 days (1.3 years); Sites of involvement: Esophagus, Middle Third.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 2.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 342 days; Days to treatment end: 370 days (1.0 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 342 days; Days to treatment end: 342 days; Treatment dose: 35 Gy; Treatment outcome: Complete Response; Number of fractions: 14; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Chemotherapy, preoperative; Radiation Therapy, NOS, preoperative.
2. Prior malignancy of the breast (histology not recorded by GDC). Laterality: Right; Age at diagnosis: 66.6 years (24,330 days); Days to diagnosis: -1,087 days (-3.0 years); AJCC staging edition: 7th; AJCC pathologic T: T1c; AJCC pathologic N: N0 (mol+); AJCC pathologic M: M0.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cyclophosphamide + Docetaxel; Days to treatment start: -1,087 days (-3.0 years); Treatment anatomic sites: Body, total.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,078 days (-3.0 years); Treatment anatomic sites: Breast.
   Treatment given: Treatment type: Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Lymph node, NOS. Age at diagnosis: 70.4 years (25,710 days); Days to diagnosis: 293 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.

Follow-up (3 entries)
- Days to follow up: 189 days; Disease response: Tumor Free.
- Day 293 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 293 days.
- Days to follow up: 477 days (1.3 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: GERD; Risk factors: GERD.
- Timepoint category: Initial Diagnosis; Weight: 100 kg; Height: 170 cm; BMI: 34.6.

Exposures
- Alcohol history: Yes; Alcohol drinks per day: 1; Alcohol days per week: 1.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 22; Tobacco smoking quit year: 1992; Age at onset: 25.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IC-A6RF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 170 mg.
  Slide TCGA-IC-A6RF-01A-01-TS1: Section location: Top; Percent tumor cells: 87; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 10; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-IC-A6RF-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-IC-A6RF-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 130 mg.
  Slide TCGA-IC-A6RF-11A-02-TSB: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 6; Percent necrosis: 0; Percent stromal cells: 94; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Cancer procurement state province: Pennsylvania; Cancer procurement city: Pittsburgh; History neoadjuvant treatment: No; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Alcohol consumption frequency: 1; History reflux disease indicator: Yes.
- Primary pathology: Esophageal tumor location centered: Mid; Histologic diagnosis: Esophagus Squamous Cell Carcinoma; Method initial path diagnosis: Endoscopic Biopsy; Lymph nodes examined: Yes; Patient to undergo surgery: Surgery already performed.
- Primary pathology, Esophageal tumor involvement sites: Esophageal tumor location involved: Mid.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast.
- Other malignancy form, Surgery: Other malignancy surgery type: Segmental mastectomy.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form, Drug treatment, Administered drug 1: Pharmaceutical therapy drug name: Cytoxan.
- Other malignancy form, Drug treatment, Administered drug 2: Pharmaceutical therapy drug name: Taxotere.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: During Enrollment it was found that the patient had a prior right breast malignancy and recieved systemic pharma treatment (cytoxan and taxotere).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 477 days; disease-specific survival: no event (censored), 477 days; disease-free interval: event (new tumor event after initially disease-free), 293 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 293 days.
